Surgical pathology report (de-identified scan), TCGA case TCGA-YS-A95B, project TCGA-MESO (Mesothelioma), tissue source site Barretos Cancer Hospital, specimen TCGA-YS-A95B-01A (Primary Tumor).

Collect date:
(MM/DD/YYYY)

PATHOLOGY REPORT:

PRIMARY SITE: Pleura

Pleural biopsy
Malign epithelioid mesothelioma.

ILD 0.3
Mesothelioma, epithelioid
malignant 9052/3
Site: Pleura NAS C384
9/18/14

Diagnosis Discrepancy	W 11/17/13	✓

Source: NCI Genomic Data Commons file 04046dc4-31ba-4984-b7f3-8259cb50bb8a (TCGA-YS-A95B.F57E6E47-4A8E-42C2-ABB8-DD81EF21DBF6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).